Somatic mutation profile of tumor specimen BA2861D (aliquot aq-BA2861D) from BEATAML1.0 case 2015, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 22.2 years (8,109 days).
Specimen BA2861D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcba0127-4319-49bb-8a43-84f681a60502.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2549D (Solid Tissue Normal), aliquot aq-BA2549D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d04fb1c-e107-4d65-a4b3-250f2c105230

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH11 | c.2278A>G p.I760V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs768205792; called by muse, varscan2
- INPP5D | c.958G>A p.V320I (on ENST00000445964 / NM_001017915.3; = p.V319I on NM_005541.5) | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as rs997884700; called by mutect2, varscan2
- LOXHD1 | c.5665G>A p.V1889I (on ENST00000642948; = p.V1827I on NM_144612.7) | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.08); catalogued as rs374269964; called by muse, mutect2, varscan2
- PARP3 | c.1187C>T p.T396I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- ANKRD55 | c.156T>A p.S52= | Silent (SNP) | VAF 15/99 reads (15%) | called by muse, mutect2, varscan2
